Gene-level copy-number profile of tumor specimen MP2PRT-PATVVI-TMP1-A from MP2PRT case MP2PRT-PATVVI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,086 days).
Specimen MP2PRT-PATVVI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 26195172-7a4f-4433-bd95-14c6bf6fe0b4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PATVVI-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/a203cb2d-bd1d-47ec-ac36-4d095aeec580

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 162; copy number 2: 41,081; copy number 3: 16,429; copy number 4: 717.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 162. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
